Somatic mutation profile of tumor specimen TCGA-CE-A27D-01A (aliquot TCGA-CE-A27D-01A-11D-A16O-08) from TCGA case TCGA-CE-A27D, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.8 years (10,536 days).
Specimen TCGA-CE-A27D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3f73ec7-2d31-47dc-ad6b-8c0516f327c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A27D-10A (Blood Derived Normal), aliquot TCGA-CE-A27D-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/437260ff-76be-4e53-b54a-cb59627e2ee9

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LCOR | c.2569A>G p.K857E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV53719208; called by muse, mutect2, varscan2
- MCMBP | c.430-1C>T p.X144_splice | Splice Site (SNP) | VAF 11/99 reads (11%) | catalogued as rs111837774, COSV63510845; called by muse, mutect2, varscan2
- PTPRZ1 | c.2537C>T p.T846I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV66446900; called by muse, mutect2
- ZNF677 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV61721871; called by muse, mutect2
- RAI14 | c.603G>A p.V201= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV54304803, COSV99464736; called by muse, mutect2, varscan2
